CCDI case PBBNRL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/217e5680-88e8-4e5f-87d5-6ad17d248d15

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 2.2 years (791 days).

Biospecimens (3 samples)
- Sample 0DDPPZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDPQ0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DDPQ1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
